Somatic mutation profile of cancer-model specimen HCM-BROD-0122-C25-85A (3D Organoid, passage 6; aliquot HCM-BROD-0122-C25-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0122-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 69.1 years (25,255 days).
Specimen HCM-BROD-0122-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8333bc2-d25b-4d3b-ad04-9f4ccbd24b92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0122-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0122-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/415ef20d-81d7-48d2-ae61-2c3b3e1b8084

The open-access MAF lists 271 somatic variants for this specimen: 221 protein-altering or splice-affecting, 41 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 210, Silent 41, Intron 6, Nonsense Mutation 5, 5'UTR 2, Splice Site 2, Frame Shift Ins 2, Nonstop Mutation 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 180/310 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 219/219 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- AATK | c.770G>T p.R257L (on ENST00000326724 / NM_001080395.3; = p.R154L on NM_004920.2) | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100452741; called by muse, mutect2, varscan2
- ADGRL1 | c.700G>A p.V234I (on ENST00000340736 / NM_001008701.3; = p.V229I on NM_014921.5) | Missense Mutation (SNP) | VAF 167/341 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as rs767200101; called by muse, mutect2, varscan2
- ATP9B | c.2483A>C p.K828T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.201); catalogued as rs766466044; called by muse, mutect2, varscan2
- BMP2K | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.722); catalogued as COSV100621410; called by muse, mutect2, varscan2
- C14orf93 | c.986A>C p.K329T | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as rs762473616; called by muse, mutect2
- CDKN2A | c.225_243dup p.V82Rfs*44 | Frame Shift Ins (INS) | VAF 208/322 reads (65%) | catalogued as COSV58726442; called by mutect2, varscan2
- CFH | c.603G>T p.E201D | Missense Mutation (SNP) | VAF 97/159 reads (61%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.765); catalogued as COSV62777516; called by muse, mutect2, varscan2
- CGB1 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 64/579 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1028339582; called by muse, mutect2, varscan2
- CNTNAP2 | c.2840T>C p.L947P | Missense Mutation (SNP) | VAF 66/509 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100673817; called by muse, mutect2, varscan2
- COL6A2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 183/350 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200387819; called by muse, mutect2, varscan2
- CORO7 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs147901888; called by muse, mutect2
- CRX | c.637T>C p.S213P | Missense Mutation (SNP) | VAF 18/674 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as CM149328; called by muse, mutect2
- CYP8B1 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 348/348 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); catalogued as rs374631131; called by muse, mutect2, varscan2
- DLC1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 114/183 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs779202345; called by muse, mutect2, varscan2
- ELOA2 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 171/171 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753794295, COSV55296866; called by muse, mutect2, varscan2
- EYA4 | c.1241G>A p.R414H (on ENST00000531901 / NM_001301013.1; = p.R408H on NM_004100.5) | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs760787542, COSV62047993, COSV62049072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EZHIP | c.184A>G p.S62G | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as rs782819844; called by muse, mutect2, varscan2
- FAM135B | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758490772; called by muse, mutect2, varscan2
- FREM2 | c.4397G>A p.R1466Q | Missense Mutation (SNP) | VAF 220/465 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as rs200981738; called by muse, mutect2, varscan2
- FSIP2 | c.19121C>G p.S6374* | Nonsense Mutation (SNP) | VAF 115/263 reads (44%) | catalogued as COSV100556906; called by muse, mutect2, varscan2
- G6PD | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 366/367 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.368); catalogued as rs1000937138, CM121674; called by muse, varscan2
- HCRTR1 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 122/200 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as rs1295959296; called by muse, mutect2, varscan2
- IQCF1 | c.554A>G p.E185G | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV58824082; called by muse, mutect2, varscan2
- KMT5A | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 120/329 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100389606; called by muse, mutect2, varscan2
- LIMCH1 | c.126A>C p.K42N | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV58272386; called by muse, mutect2, varscan2
- LRRC15 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 180/490 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as rs145451484; called by muse, mutect2, varscan2
- LVRN | c.999A>C p.K333N | Missense Mutation (SNP) | VAF 38/489 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1347028884; called by muse, mutect2
- MRPL37 | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749703731; called by muse, mutect2, varscan2
- MYH8 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs1158371179; called by muse, mutect2, varscan2
- NAGA | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 86/421 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); catalogued as rs777425990, COSV67170098; called by muse, mutect2, varscan2
- NEIL3 | c.1770C>G p.F590L | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99220952; called by muse, mutect2, varscan2
- OR8G1 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 178/384 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as rs753993339; called by muse, mutect2, varscan2
- OVGP1 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 91/319 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs752564902, COSV63858895; called by muse, mutect2, varscan2
- PACS2 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 209/379 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs781917054, COSV57652082; called by muse, mutect2, varscan2
- PCDH8 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 260/532 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100131871; called by muse, mutect2, varscan2
- PLD5 | c.1003G>A p.D335N (on ENST00000442594; = p.D273N on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/316 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); catalogued as COSV59153640; called by muse, mutect2, varscan2
- PXDNL | c.2329C>A p.L777I | Missense Mutation (SNP) | VAF 362/535 reads (68%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV62493022; called by muse, mutect2, varscan2
- PYGL | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 219/396 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs562250944, COSV53588107; called by muse, mutect2, varscan2
- RABIF | c.269A>T p.K90M | Missense Mutation (SNP) | VAF 67/349 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66131318; called by muse, mutect2, varscan2
- RGS12 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 325/490 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148172496; called by muse, mutect2, varscan2
- RNF115 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs782644559; called by muse, varscan2
- SESTD1 | c.885A>C p.Q295H | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV58930263; called by muse, mutect2
- SLC17A5 | c.887T>G p.V296G | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63287521; called by muse, mutect2, varscan2
- SLC30A1 | c.595T>A p.S199T | Missense Mutation (SNP) | VAF 65/405 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs1162589169; called by muse, mutect2, varscan2
- SPATA31E1 | c.1694A>G p.E565G | Missense Mutation (SNP) | VAF 66/420 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs1426214530; called by muse, mutect2, varscan2
- SRRM4 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 208/712 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as rs1326520484; called by muse, mutect2, varscan2
- SYNM | c.2227G>A p.V743I | Missense Mutation (SNP) | VAF 178/546 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.668); catalogued as rs782035534; called by muse, mutect2, varscan2
- TENM4 | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 114/420 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs763663817; called by muse, mutect2, varscan2
- TLR3 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 17/609 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57168340; called by muse, mutect2
- TLR5 | c.1861C>T p.L621F | Missense Mutation (SNP) | VAF 97/271 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1482385644; called by muse, mutect2, varscan2
- TMPRSS12 | c.537A>T p.K179N | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV68255825; called by muse, mutect2
- TPTE2 | c.773G>A p.R258Q (on ENST00000400230 / NM_199254.2; = p.R181Q on NM_130785.3) | Missense Mutation (SNP) | VAF 78/357 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs772456088, COSV55018040, COSV55018075; called by muse, mutect2
- TRAPPC9 | c.548A>C p.E183A | Missense Mutation (SNP) | VAF 48/524 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66903005; called by muse, mutect2
- TRPM6 | c.4513A>T p.R1505* | Nonsense Mutation (SNP) | VAF 44/537 reads (8%) | catalogued as COSV100667079; called by muse, mutect2
- TTC21B | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 29/362 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs77758946, COSV54630113; called by muse, mutect2
- TTN | c.77404C>T p.R25802C (on ENST00000591111; = p.R18378C on NM_003319.4) | Missense Mutation (SNP) | VAF 74/372 reads (20%) | PolyPhen probably damaging (0.917); catalogued as rs755125180; called by muse, mutect2, varscan2
- UNC79 | c.2557G>A p.E853K (on ENST00000393151 / NM_001346218.2; = p.E676K on NM_020818.5) | Missense Mutation (SNP) | VAF 324/824 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs765545121, COSV56389320; called by muse, mutect2, varscan2
- USP35 | c.2150A>G p.E717G | Missense Mutation (SNP) | VAF 77/564 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs868575903; called by muse, mutect2, varscan2
- ZAN | c.5699_5701del p.N1900del | In Frame Del (DEL) | VAF 286/431 reads (66%) | catalogued as rs781681980; called by pindel, varscan2
- ZFP57 | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 25/823 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV65305723; called by muse, mutect2
- ZNF568 | c.617A>T p.E206V | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as COSV100451383; called by muse, mutect2
- ZNF736 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV61908332; called by muse, mutect2
- ABCB6 | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 80/267 reads (30%) | called by muse, mutect2, varscan2
- ABLIM3 | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2
- ADGRD1 | c.2342A>T p.N781I | Missense Mutation (SNP) | VAF 65/417 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- ADIPOR2 | c.739T>G p.F247V | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- ADPRHL1 | c.4814A>G p.Q1605R | Missense Mutation (SNP) | VAF 56/564 reads (10%) | SIFT tolerated, low confidence (1); called by muse, mutect2, varscan2
- ALG10B | c.739T>G p.L247V | Missense Mutation (SNP) | VAF 19/285 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.065); called by muse, mutect2
- ALK | c.317C>A p.P106Q | Missense Mutation (SNP) | VAF 25/475 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2
- ANKS1A | c.3327A>C p.Q1109H | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ANO8 | c.1894A>G p.S632G | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- ARAP3 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 48/598 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- ARHGEF28 | c.10A>C p.S4R | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ARHGEF6 | c.1889T>G p.L630R | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ASPM | c.592T>G p.L198V | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- ATAD2B | c.1528T>G p.L510V | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ATP10B | c.3134A>C p.K1045T | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2
- AXDND1 | c.2762C>T p.A921V | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- B4GALT6 | c.403T>G p.F135V | Missense Mutation (SNP) | VAF 23/589 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2
- BRAT1 | c.862A>C p.S288R | Missense Mutation (SNP) | VAF 15/534 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- C1orf226 | c.650A>C p.E217A | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2
- C4orf48 | c.286T>C p.*96Rext*7 | Nonstop Mutation (SNP) | VAF 16/424 reads (4%) | called by muse, mutect2
- CACNA1D | c.1625C>G p.S542C (on ENST00000350061 / NM_001128840.3; = p.S562C on NM_000720.4) | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CACNB4 | c.457A>C p.S153R | Missense Mutation (SNP) | VAF 39/385 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CCDC175 | c.1726A>G p.R576G | Missense Mutation (SNP) | VAF 32/478 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- CCR8 | c.223T>A p.L75M | Missense Mutation (SNP) | VAF 128/395 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDC34 | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CHST1 | c.242A>C p.N81T | Missense Mutation (SNP) | VAF 20/703 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CKAP2 | c.658C>T p.P220S (on ENST00000378037 / NM_001098525.2; = p.P219S on NM_018204.5) | Missense Mutation (SNP) | VAF 117/481 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CKMT1A | c.887T>G p.L296R | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.31); called by muse, mutect2
- CNTN6 | c.1748T>A p.L583Q | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COL14A1 | c.4127A>C p.K1376T | Missense Mutation (SNP) | VAF 42/502 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.392); called by muse, mutect2
- CPT1B | c.1679A>C p.K560T | Missense Mutation (SNP) | VAF 29/684 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRYBG2 | c.3552A>C p.E1184D | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSPG4 | c.397T>A p.S133T | Missense Mutation (SNP) | VAF 116/548 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNND1 | c.2842T>G p.L948V (on ENST00000399050 / NM_001085458.2; = p.L921V on NM_001331.3) | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP4F2 | c.1453A>C p.T485P | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH11 | c.496-1G>A p.X166_splice | Splice Site (SNP) | VAF 52/172 reads (30%) | called by muse, mutect2, varscan2
- DNAJC18 | c.892A>C p.T298P | Missense Mutation (SNP) | VAF 11/396 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2
- DPYSL3 | c.696A>C p.E232D | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- EDRF1 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EFHC2 | c.1325T>A p.V442D | Missense Mutation (SNP) | VAF 116/117 reads (99%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMSY | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBXL18 | c.1525T>G p.S509A | Missense Mutation (SNP) | VAF 128/547 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FHL1 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 64/481 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- FOXP2 | c.362T>G p.L121R | Missense Mutation (SNP) | VAF 130/346 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FRAS1 | c.11209T>C p.F3737L | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GABRA5 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GCKR | c.713A>G p.E238G | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); called by muse, mutect2
- GPN2 | c.293A>T p.K98M | Missense Mutation (SNP) | VAF 79/396 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- GRIA1 | c.480A>C p.K160N | Missense Mutation (SNP) | VAF 43/354 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- GTSE1 | c.1383G>C p.K461N | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- GZMA | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 90/372 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- HIPK2 | c.3187A>G p.T1063A | Missense Mutation (SNP) | VAF 25/673 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- HMGA1 | c.140A>G p.E47G (on ENST00000311487 / NM_001319082.2; = p.E36G on NM_002131.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- IQCC | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQCN | c.2336A>C p.K779T | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- JADE1 | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNB2 | c.2228A>C p.D743A | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.993); called by muse, mutect2
- KCNH7 | c.1414A>C p.T472P | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KPNA6 | c.1540C>G p.Q514E | Missense Mutation (SNP) | VAF 277/434 reads (64%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT5 | c.1379A>C p.K460T | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LDLRAD3 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 52/732 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2
- LPCAT2 | c.1057T>G p.L353V | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- LRRFIP1 | c.72A>C p.E24D | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEB1 | c.11G>C p.G4A | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAN1C1 | c.808T>G p.S270A | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.324); called by muse, mutect2
- MATN2 | c.1573A>G p.K525E | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- MEPE | c.1453A>G p.M485V | Missense Mutation (SNP) | VAF 199/296 reads (67%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRTFA | c.1381T>G p.L461V | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- MTG1 | c.78C>G p.D26E | Missense Mutation (SNP) | VAF 72/502 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MTIF3 | c.25T>G p.L9V | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.255); called by muse, mutect2
- MUC5AC | c.1511A>C p.K504T | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MX1 | c.1556A>C p.K519T | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2
- NADSYN1 | c.1657T>A p.F553I | Missense Mutation (SNP) | VAF 77/324 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- NBEAL1 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 173/225 reads (77%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NFYB | c.249A>T p.K83N | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NLRC5 | c.1230A>C p.Q410H | Missense Mutation (SNP) | VAF 27/580 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2
- OR13H1 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 138/330 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR2L8 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR51E2 | c.667A>T p.T223S | Missense Mutation (SNP) | VAF 26/498 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.209); called by muse, mutect2
- OR51T1 | c.853T>G p.L285V | Missense Mutation (SNP) | VAF 31/388 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.027); called by muse, mutect2
- PAK1IP1 | c.106T>G p.F36V | Missense Mutation (SNP) | VAF 137/208 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAMR1 | c.1072A>T p.R358* (on ENST00000619888 / NM_001001991.3; = p.R375* on NM_015430.4) | Nonsense Mutation (SNP) | VAF 17/432 reads (4%) | called by muse, mutect2
- PCDH8 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 420/815 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, varscan2
- PCDHGA2 | c.17A>C p.K6T | Missense Mutation (SNP) | VAF 18/347 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); called by muse, mutect2
- PCNX1 | c.6691A>C p.S2231R | Missense Mutation (SNP) | VAF 59/766 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2
- PCSK1N | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE4D | c.893A>C p.H298P (on ENST00000340635 / NM_001104631.2; = p.H162P on NM_006203.4) | Missense Mutation (SNP) | VAF 91/372 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- PDS5A | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 14/381 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- PFDN4 | c.240A>C p.Q80H | Missense Mutation (SNP) | VAF 31/391 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); called by muse, mutect2
- PGM2L1 | c.360A>C p.Q120H | Missense Mutation (SNP) | VAF 70/269 reads (26%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PHF11 | c.701T>G p.L234R | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2
- PIH1D1 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 45/407 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCE1 | c.6461_6465dup p.P2156Kfs*26 | Frame Shift Ins (INS) | VAF 84/312 reads (27%) | called by mutect2, varscan2
- PRAG1 | c.2957A>G p.E986G | Missense Mutation (SNP) | VAF 74/428 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- PRAMEF14 | c.1095A>C p.Q365H | Missense Mutation (SNP) | VAF 41/422 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRDM2 | c.3523A>G p.T1175A | Missense Mutation (SNP) | VAF 13/449 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- QRICH1 | c.1885T>C p.F629L | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RFX1 | c.494A>T p.N165I | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- RNF6 | c.403A>G p.R135G | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RRNAD1 | c.59A>T p.N20I | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.043); called by muse, mutect2
- RSF1 | c.3720C>G p.H1240Q | Missense Mutation (SNP) | VAF 232/388 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- RTN1 | c.2125A>G p.M709V | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- SALL2 | c.2096A>C p.K699T | Missense Mutation (SNP) | VAF 76/872 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERGEF | c.1186T>C p.S396P | Missense Mutation (SNP) | VAF 22/583 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERINC1 | c.220A>C p.N74H | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SHANK1 | c.5281G>A p.A1761T | Missense Mutation (SNP) | VAF 198/609 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC5 | c.533T>A p.F178Y | Missense Mutation (SNP) | VAF 126/454 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC26A8 | c.1313T>A p.V438E | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- SLC35F3 | c.250A>T p.T84S (on ENST00000366617 / NM_001300845.1; = p.T153S on NM_173508.4) | Missense Mutation (SNP) | VAF 26/622 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- SLC36A4 | c.158T>G p.L53R | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.635); called by muse, mutect2
- SLC6A1 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 32/779 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.15); called by muse, mutect2
- SLC6A15 | c.2024G>T p.S675I | Missense Mutation (SNP) | VAF 96/328 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by mutect2, varscan2
- SLC9A5 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 83/470 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC9C2 | c.1650A>C p.Q550H | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SNAPC1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 93/232 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- SOS1 | c.1683A>T p.E561D | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- SP100 | c.2104T>G p.S702A | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.248); called by muse, mutect2
- SPEM2 | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 94/467 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPG7 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 14/417 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2
- SPRING1 | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 74/460 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- SRRM3 | c.1625A>G p.H542R | Missense Mutation (SNP) | VAF 27/977 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2
- SYNE1 | c.10651T>C p.S3551P (on ENST00000367255 / NM_182961.4; = p.S3558P on NM_033071.3) | Missense Mutation (SNP) | VAF 35/424 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- SYT3 | c.217T>C p.F73L | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- TAS2R14 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TBC1D12 | c.1290A>C p.K430N | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- TMEM100 | c.23A>G p.E8G | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); called by muse, mutect2
- TMEM175 | c.928T>C p.F310L | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- TNK2 | c.371A>C p.K124T | Missense Mutation (SNP) | VAF 74/855 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- TPM1 | c.35A>T p.K12M | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRDJ4 | c.16T>A p.F6I | Missense Mutation (SNP) | VAF 66/541 reads (12%) | called by muse, mutect2, varscan2
- TRIM22 | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 118/447 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TRIM64B | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 28/1005 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- TRIM66 | c.3067G>T p.E1023* | Nonsense Mutation (SNP) | VAF 170/420 reads (40%) | called by muse, mutect2, varscan2
- TRIOBP | c.4535T>A p.L1512H | Missense Mutation (SNP) | VAF 30/519 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.095); called by muse, mutect2
- TRMT5 | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 149/364 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC30B | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 40/471 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.17); called by muse, mutect2
- TTC34 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 239/664 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TTN | c.37403T>C p.L12468P (on ENST00000591111; = p.L5044P on NM_003319.4) | Missense Mutation (SNP) | VAF 31/331 reads (9%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- UBE2M | c.275A>T p.K92M | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USE1 | c.68A>G p.E23G | Missense Mutation (SNP) | VAF 76/358 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- USP44 | c.1697T>C p.L566P | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VRTN | c.263A>T p.E88V | Missense Mutation (SNP) | VAF 39/1137 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- VWA7 | c.1655A>G p.E552G | Missense Mutation (SNP) | VAF 58/386 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, varscan2
- WDR72 | c.2145A>C p.R715S | Missense Mutation (SNP) | VAF 11/357 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- WHAMM | c.2299A>G p.K767E | Missense Mutation (SNP) | VAF 163/592 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZBBX | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 163/363 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZFHX3 | c.5971T>G p.L1991V | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2
- ZKSCAN7 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2
- ZMYM6 | c.1093T>G p.S365A | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- ZNF341 | c.1504A>C p.S502R (on ENST00000375200 / NM_001282935.1; = p.S495R on NM_032819.4) | Missense Mutation (SNP) | VAF 23/798 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.676); called by muse, mutect2
- ZNF462 | c.2810T>G p.V937G | Missense Mutation (SNP) | VAF 18/482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF480 | c.200-1G>A p.X67_splice | Splice Site (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- ZNF543 | c.1394A>G p.D465G | Missense Mutation (SNP) | VAF 46/428 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF600 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF655 | c.409A>C p.S137R | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF710 | c.1624T>C p.S542P | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); called by muse, mutect2
- ZNF711 | c.1430A>G p.K477R | Missense Mutation (SNP) | VAF 26/383 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); called by muse, mutect2
- ABHD11 | c.264C>A p.I88= | Silent (SNP) | VAF 222/325 reads (68%) | called by muse, mutect2, varscan2
- ACTN2 | c.1287C>T p.Y429= | Silent (SNP) | VAF 37/466 reads (8%) | catalogued as rs764881077, COSV63977582; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- ARID2 | c.2814T>G p.T938= | Silent (SNP) | VAF 44/481 reads (9%) | called by muse, mutect2
- ARMC8 | c.1335A>T p.V445= (on ENST00000469044 / NM_001363941.2; = p.V431= on NM_015396.6) | Silent (SNP) | VAF 149/299 reads (50%) | called by muse, mutect2, varscan2
- ARMH4 | c.540A>G p.T180= | Silent (SNP) | VAF 96/464 reads (21%) | called by muse, mutect2, varscan2
- ASTN2 | c.1578C>T p.C526= (on ENST00000313400 / NM_001365069.1; = p.C475= on NM_014010.5) | Silent (SNP) | VAF 59/252 reads (23%) | catalogued as rs140337955; called by muse, varscan2
- CDHR4 | c.2208T>G p.T736= | Silent (SNP) | VAF 82/235 reads (35%) | catalogued as rs1163910865; called by muse, mutect2, varscan2
- CEP290 | c.3018A>G p.Q1006= | Silent (SNP) | VAF 13/235 reads (6%) | called by muse, mutect2
- CMYA5 | c.1848T>G p.V616= | Silent (SNP) | VAF 78/343 reads (23%) | called by muse, mutect2, varscan2
- CRAT | c.942C>T p.S314= | Silent (SNP) | VAF 116/440 reads (26%) | called by muse, mutect2, varscan2
- CSF2RA | c.951T>C p.S317= | Silent (SNP) | VAF 58/370 reads (16%) | catalogued as rs1436224543; called by muse, mutect2, varscan2
- CTAGE6 | c.1341T>C p.T447= | Silent (SNP) | VAF 38/574 reads (7%) | called by muse, mutect2
- CTNNA2 | c.2448T>A p.T816= | Silent (SNP) | VAF 185/230 reads (80%) | catalogued as COSV58150367; called by muse, mutect2, varscan2
- DNMT3B | c.2073G>T p.P691= | Silent (SNP) | VAF 88/502 reads (18%) | catalogued as COSV99143362; called by muse, mutect2, varscan2
- EHD3 | c.1242C>T p.F414= | Silent (SNP) | VAF 389/389 reads (100%) | catalogued as rs771037253, COSV59029309; called by muse, mutect2, varscan2
- EPB41L4B | c.879G>A p.P293= | Silent (SNP) | VAF 219/219 reads (100%) | catalogued as rs770409658, COSV65797144; called by muse, mutect2, varscan2
- FGD4 | c.354T>G p.A118= | Silent (SNP) | VAF 57/331 reads (17%) | called by muse, mutect2, varscan2
- FLG | c.10527T>G p.A3509= | Silent (SNP) | VAF 14/382 reads (4%) | called by muse, mutect2
- GDF10 | c.192C>T p.A64= | Silent (SNP) | VAF 88/549 reads (16%) | catalogued as rs990386827; called by muse, mutect2, varscan2
- HDGF | c.291T>G p.A97= | Silent (SNP) | VAF 13/351 reads (4%) | called by muse, mutect2
- HSP90B1 | c.1995A>G p.Q665= | Silent (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- KLF6 | c.360T>C p.S120= | Silent (SNP) | VAF 12/394 reads (3%) | called by muse, mutect2
- KRT31 | c.651C>T p.P217= | Silent (SNP) | VAF 138/483 reads (29%) | called by muse, mutect2, varscan2
- KRTAP11-1 | c.375C>T p.G125= | Silent (SNP) | VAF 161/305 reads (53%) | catalogued as rs143272687; called by muse, mutect2, varscan2
- MTIF3 | c.231C>T p.N77= | Silent (SNP) | VAF 55/460 reads (12%) | catalogued as rs149627575; called by muse, mutect2, varscan2
- NRXN3 | c.1647G>A p.P549= (on ENST00000557594 / NM_001272020.2; = p.P973= on NM_004796.6) | Silent (SNP) | VAF 387/710 reads (55%) | catalogued as rs143519887, COSV55335758; called by muse, mutect2, varscan2
- OR2B6 | c.468A>C p.S156= | Silent (SNP) | VAF 34/382 reads (9%) | catalogued as COSV99773875; called by muse, mutect2
- RALGDS | c.2289A>T p.S763= | Silent (SNP) | VAF 87/447 reads (19%) | called by muse, mutect2, varscan2
- RIMKLB | c.1020T>C p.A340= | Silent (SNP) | VAF 46/557 reads (8%) | called by muse, mutect2
- ROS1 | c.1869T>A p.T623= | Silent (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- RP1 | c.5823T>C p.S1941= | Silent (SNP) | VAF 28/290 reads (10%) | called by muse, mutect2
- RYR1 | c.1020C>T p.Y340= | Silent (SNP) | VAF 314/454 reads (69%) | catalogued as rs778349211; called by muse, mutect2, varscan2
- SNCAIP | c.570A>G p.K190= | Silent (SNP) | VAF 22/381 reads (6%) | catalogued as rs769891324; called by muse, mutect2
- ST8SIA1 | c.1011C>T p.I337= | Silent (SNP) | VAF 201/297 reads (68%) | catalogued as rs375498016; called by muse, varscan2
- SYT12 | c.594G>A p.P198= | Silent (SNP) | VAF 235/404 reads (58%) | catalogued as rs762972720; called by muse, mutect2, varscan2
- TMEM229A | c.999T>G p.A333= | Silent (SNP) | VAF 18/594 reads (3%) | called by muse, mutect2
- TNFRSF8 | c.258T>G p.T86= | Silent (SNP) | VAF 45/217 reads (21%) | called by muse, mutect2, varscan2
- ZC3H11B | c.1635G>A p.E545= | Silent (SNP) | VAF 37/188 reads (20%) | catalogued as rs1275911285; called by muse, mutect2, varscan2
- ZFYVE9 | c.375A>G p.Q125= | Silent (SNP) | VAF 107/361 reads (30%) | catalogued as rs778573791; called by muse, mutect2, varscan2
- ZNF25 | c.804C>A p.S268= | Silent (SNP) | VAF 51/420 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN31 | c.657T>G p.T219= | Silent (SNP) | VAF 16/448 reads (4%) | called by muse, mutect2
- APOBEC3F | c.172-821T>C | Intron (SNP) | VAF 19/669 reads (3%) | called by muse, mutect2
- CPED1 | c.2311-4587C>T | Intron (SNP) | VAF 96/335 reads (29%) | catalogued as COSV60000948; called by muse, mutect2, varscan2
- EML2 | chr19:45607085 A>C | 3'Flank (SNP) | VAF 60/499 reads (12%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-6525G>A | Intron (SNP) | VAF 147/317 reads (46%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+10712T>G | Intron (SNP) | VAF 49/357 reads (14%) | called by muse, mutect2, varscan2
- NAA60 | c.-46A>G | 5'UTR (SNP) | VAF 22/228 reads (10%) | catalogued as rs1053694190; called by muse, mutect2
- RALYL | c.-24+585G>A | Intron (SNP) | VAF 116/381 reads (30%) | catalogued as COSV72819811; called by muse, mutect2, varscan2
- TNS1 | c.-85T>G | 5'UTR (SNP) | VAF 14/390 reads (4%) | called by muse, mutect2
- UBR2 | c.1281+80C>T | Intron (SNP) | VAF 51/213 reads (24%) | catalogued as rs539939419; called by muse, mutect2, varscan2
